Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016447-09A.1 (aliquot TARGET-15-SJMPAL016447-09A.1-01D) from TARGET case TARGET-15-SJMPAL016447, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,285 days).
Specimen TARGET-15-SJMPAL016447-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41865c9e-c619-4d8d-a79d-20b515a37ac3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016447-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016447-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4971fbf-085a-4d83-9e4a-656d42dbcc94

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 2, Frame Shift Ins 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 36/102 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, varscan2
- ARHGEF10 | c.1057G>A p.A353T (on ENST00000398564; = p.A328T on NM_014629.4) | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs977083004, COSV50643604; called by muse, mutect2, varscan2
- COL26A1 | c.886G>A p.V296M (on ENST00000313669 / NM_001278563.3; = p.V294M on NM_133457.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs768037612; called by muse, varscan2
- DNM2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752080566, COSV100117563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752810646, COSV99251207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- KCNA4 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV60251905; called by muse, mutect2, varscan2
- NOTCH1 | c.7312_7313dup p.S2439Rfs*39 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | catalogued as COSV53047255, COSV53052980, COSV53102645; called by mutect2, pindel, varscan2
- PLSCR5 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs372370688, COSV71649018; called by muse, mutect2, varscan2
- PPP3CA | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59919482; called by muse, mutect2, varscan2
- RTF1 | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.998); catalogued as COSV101048095; called by muse, mutect2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel
- FADS3 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- GBX1 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.122); called by muse, mutect2
- NTNG1 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKA1 | c.2666G>C p.S889T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RUFY4 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2
- TRPS1 | c.1222G>T p.D408Y (on ENST00000220888 / NM_001330599.2; = p.D421Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.54059G>T p.G18020V (on ENST00000591111; = p.G10596V on NM_003319.4) | Missense Mutation (SNP) | VAF 119/254 reads (47%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF382 | c.956C>A p.T319K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DSG2 | c.1872C>A p.L624= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as rs1321243877; called by muse, varscan2
- NACC1 | c.1539C>A p.A513= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- G3BP1 | c.351+1001C>T | Intron (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- GTSF1 | c.118-11dup | Intron (INS) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
